Gene-level copy-number profile of tumor specimen BLGSP-71-06-00159-01A from CGCI case BLGSP-71-06-00159, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Primary diagnosis: Burkitt-like lymphoma; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 2.7 years (980 days).
Specimen BLGSP-71-06-00159-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e56c1a40-b685-4462-ba23-a1c8acee6200.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00159-12A (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/25673c8d-0de8-4f21-80fd-ced7cdcfa2b0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 132; copy number 1: 3,617; copy number 2: 54,439; copy number 3: 717.

Homozygous deletions (total copy number 0; autosomes only): 132 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:69,560,191–69,624,049, 2 genes: GTF2H2C, NAIPP3.
- chr8:7,881,392–7,896,716, 3 genes: DEFB103A, HSPD1P2, DEFB4A.
- chr14:105,851,705–106,211,453, 65 genes (within-gene range 0–2) (broad region; genes not listed).
- chr22:22,420,326–22,893,818, 62 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 761. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
